Somatic mutation profile of tumor specimen BA3221D (aliquot aq-BA3221D) from BEATAML1.0 case 2645, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.6 years (16,645 days).
Specimen BA3221D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbc2016f-7edd-4983-b780-d231987dbf26.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3331D (Solid Tissue Normal), aliquot aq-BA3331D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5cdf36f-911e-498f-af11-690553eb3325

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM132D | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV70602594; called by muse, mutect2, varscan2
